Gene-level copy-number profile of tumor specimen C3N-01416-03 from CPTAC case C3N-01416, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.2 years (24,540 days).
Specimen C3N-01416-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3cecec76-7140-448f-864a-5fa5ae7210e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01416-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/646b9634-fccb-440d-8c4d-08674b6d963d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,992; copy number 2: 34,667; copy number 3: 7,170; copy number 4: 154; copy number 5: 84; copy number 6: 108; copy number 9: 135; copy number 11: 2; copy number 13: 42; copy number 14: 18; copy number 15: 5; copy number 16: 10; copy number 17: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 363 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,173,141–1,900,493, 29 genes, copy number 5: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4.
- chr5:38,474,668–44,658,569, 94 genes, copy number 6 (broad region; genes not listed).
- chr12:67,265,842–80,937,925, 212 genes, copy number 5–16 (within-gene range 1–16) (broad region; genes not listed).
- chr13:102,596,986–103,444,968, 16 genes, copy number 5: TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, LINC01309, ATP6V1G1P7.
- chr13:111,316,184–112,331,225, 12 genes, copy number 5: TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044.

Autosomal genes at a single copy (total copy number 1): 15,244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
